Surgical pathology report (de-identified scan), TCGA case TCGA-FG-7637, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-7637-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS

A. POSTERIOR RIGHT TEMPORAL OCCIPITAL TUMOR, BIOPSY:
-- INFILTRATING GLIOMA.

B. RIGHT TEMPORAL TIP, BIOPSY:
-- INFILTRATING GLIOMA.

C. RIGHT TEMPORAL OCCIPITAL BRAIN TUMOR, REMOVAL:
-- MIXED OLIGO ASTROCYTOMA (WHO GRADE II).

Note: The tumor demonstrates geographically separate areas of astrocytic and oligodendroglial differentiation. Hypercellularity is seen only within the oligodendroglial regions. Mitotic figures are not identified. A focus of coagulative tumor necrosis lacking pseudo-palisading is identified within block C1. Microvascular proliferation is not identified. An addendum will be issued pending analyses for deletions on chromosomes 1 and 19.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A: Intraoperative microscopic diagnosis: Anaplastic astrocytoma

B: Intraoperative microscopic diagnosis: Infiltrating glioma

Addendum

Addendum Diagnosis

Fluorescence in situ hybridization, performed at [REDACTED], demonstrates loss of both chromosomes 1p and 19q. A copy of the report is on file in the Department of Pathology.

Electronically Signed Out By

Clinical History:

right temporal occipital brain tumor

Specimens Submitted As:

A: POST R TEMPORAL OCCIPITAL TUMOR

B: TEMPORAL TIP

C: RIGHT TEMPORAL -OCCIPITAL BRAIN TUMOR

Gross Description:

[page 2 of 2]
A: Received fresh requesting intraoperative consultation labeled with patient name, medical record number, and "posterior right temporal occipital tumor" and consists of one soft, tan-white, fragment of tissue measuring 0.9 x 0.6 x 0.5 cm. Touch preparations are performed. The specimen is entirely submitted for frozen section analysis in two parts. The specimen is entirely submitted for permanent section analysis in 2 cassettes

B: Received fresh requesting intraoperative consultation and labeled with patient name, medical record number, and "temporal tip" and consists of multiple irregular, pink-tan, soft, glistening, fragments of tissue with an aggregate measure of 2.4 x 0.6 x 0.5 cm. Representative sections have been submitted for frozen section analysis. The remainder of the specimen is submitted entirely in cassettes FS B1 and B2

C: Received in formalin labeled with the patient's name and number, are multiple irregular, tan to brown, soft, cerebriform tissue fragments measuring in aggregate 3.3 x 2.8 x 1.5 cm. Submitted entirely in four cassettes.

Source: NCI Genomic Data Commons file 4b66fb3e-814a-4cab-ad0a-4d343868b1ca (TCGA-FG-7637.9FDC723F-1CBA-4660-8B6E-9C81E86A24E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).